Gene-level copy-number profile of specimen HCM-BROD-0053-C49-85M from HCMI case HCM-BROD-0053-C49, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Epithelioid sarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; Tumor grade: G2; Age at diagnosis: 16.0 years (5,851 days).
Specimen HCM-BROD-0053-C49-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 14.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 2db233b4-0d63-4361-88b0-0903a9386ad8.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0053-C49-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,234 have no estimate.
https://portal.gdc.cancer.gov/files/d427416f-8c1d-43b9-be01-f1e26ae7a933

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 465; copy number 2: 4,956; copy number 3: 11,895; copy number 4: 36,571; copy number 5: 1,574; copy number 6: 1,777; copy number 7: 190; copy number 8: 27; copy number 9: 895; copy number 10: 16; copy number 11: 20; copy number 12: 2.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr22:18,422,244–18,500,594, 1 gene (within-gene range 0–8): FAM230A.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 933 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:5,274,369–9,851,386, 101 genes, copy number 9 (broad region; genes not listed).
- chr7:12,726,152–57,837,046, 794 genes, copy number 9 (broad region; genes not listed).
- chr22:19,969,896–20,495,844, 38 genes, copy number 10–12 (within-gene range 6–12): ARVCF, TANGO2, MIR185, AC006547.1, AC006547.3, Metazoa_SRP, DGCR8, MIR3618, MIR1306, AC006547.2, TRMT2A, MIR6816, RANBP1, SNORA77B, ZDHHC8, CCDC188, AC007663.2, LINC00896, RTN4R, MIR1286, AC007663.1, DGCR6L, AC007663.4, AC007663.3, FAM230G, AC007731.2, AC007731.5, USP41, ZNF74, RNU6-225P, SCARF2, AC007731.4, KLHL22, AC007731.1, RNY1P9, Y_RNA, RN7SL812P, KRT18P5.

Autosomal genes at a single copy (total copy number 1): 465. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
